Somatic mutation profile of tumor specimen 0DV14Y from CCDI case PBCKXS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.8 years (2,471 days).
Specimen 0DV14Y: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3f48434d-0663-4a19-a434-2d3d91371df2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DV14I (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/113a2129-913c-46d9-9183-a96084823667

The open-access MAF lists 20 somatic variants for this specimen: 12 protein-altering or splice-affecting, 4 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 4, Intron 2, 5'UTR 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HIPK1 | c.3338C>T p.T1113M (on ENST00000369558 / NM_001369806.1; = p.T719M on NM_181358.2) | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs751762183, COSV61250626; called by muse, mutect2, varscan2
- KCNK1 | c.544G>A p.V182I | Missense Mutation (SNP) | VAF 100/335 reads (30%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs199630093, COSV64034520; called by muse, mutect2, varscan2
- MYRF | c.2416G>A p.V806M | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.613); catalogued as rs1349917549, COSV53896132; called by muse, varscan2
- OR4S2 | c.613G>T p.A205S | Missense Mutation (SNP) | VAF 119/323 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs1162715260; called by muse, mutect2, varscan2
- RNF14 | c.1112A>G p.N371S | Missense Mutation (SNP) | VAF 103/327 reads (31%) | SIFT tolerated (0.52); PolyPhen benign (0.012); catalogued as rs759685165; called by muse, mutect2, varscan2
- CEACAM18 | c.817C>A p.L273I | Missense Mutation (SNP) | VAF 37/157 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- HJV | c.1027G>T p.A343S (on ENST00000336751 / NM_213653.4; = p.A230S on NM_145277.5) | Missense Mutation (SNP) | VAF 56/229 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- HMMR | c.1782+4dup p.X594_splice | Splice Site (INS) | VAF 36/170 reads (21%) | called by mutect2, varscan2
- SLC17A9 | c.1305C>A p.D435E | Missense Mutation (SNP) | VAF 120/333 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SRCAP | c.2777C>T p.A926V | Missense Mutation (SNP) | VAF 47/325 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- TRIM36 | c.1475A>G p.K492R | Missense Mutation (SNP) | VAF 114/327 reads (35%) | SIFT tolerated (0.5); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- USP32 | c.1058T>G p.L353W | Missense Mutation (SNP) | VAF 45/597 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.341); called by muse, mutect2
- NIPBL | c.7338G>A p.P2446= | Silent (SNP) | VAF 51/318 reads (16%) | catalogued as rs1303071370; called by muse, mutect2, varscan2
- OR2W1 | c.861G>A p.P287= | Silent (SNP) | VAF 40/480 reads (8%) | catalogued as rs1003955722, COSV65851356; called by muse, mutect2
- PRODH2 | c.1101G>A p.A367= (on ENST00000301175; = p.A291= on NM_021232.2 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 24/232 reads (10%) | catalogued as rs755650009; called by muse, mutect2, varscan2
- ZNF335 | c.3018G>A p.P1006= | Silent (SNP) | VAF 96/437 reads (22%) | catalogued as rs758841641; called by muse, mutect2, varscan2
- ATP13A2 | c.1542+71C>T | Intron (SNP) | VAF 15/53 reads (28%) | catalogued as rs769412081; called by muse, mutect2, varscan2
- KHDC1 | c.-61G>A | 5'UTR (SNP) | VAF 6/38 reads (16%) | called by mutect2, varscan2
- SMIM10L2B | c.-16C>T | 5'UTR (SNP) | VAF 10/82 reads (12%) | called by muse, mutect2, varscan2
- UNC13D | c.570-91_570-90del | Intron (DEL) | VAF 6/30 reads (20%) | called by mutect2, varscan2
